Somatic mutation profile of tumor specimen PCProject_0364_T2_WES (aliquot PCProject_0364_T2_WES_1) from CMI case PCProject_0364, project CMI-MPC: Count Me In (CMI): The Metastatic Prostate Cancer (MPC) Project. Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 71.7 years (26,174 days).
Specimen PCProject_0364_T2_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Prostate; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ea48bf83-3e8c-4b7d-8068-6dc66e64f781.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen PCProject_0364_SALIVA (DNA), aliquot PCProject_0364_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/82a4e6c8-1b5d-4506-9219-977adc60e0c5

The open-access MAF lists 29 somatic variants for this specimen: 19 protein-altering or splice-affecting, 6 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Silent 6, Intron 3, Frame Shift Del 2, Nonsense Mutation 1, 3'UTR 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.752T>A p.I251N | Missense Mutation (SNP) | VAF 92/541 reads (17%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (0.94); catalogued as rs730882027, COSV52728902, COSV52741592, COSV52816233, COSV53108676; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ARID1B | c.77A>C p.K26T | Missense Mutation (SNP) | VAF 30/196 reads (15%) | SIFT deleterious, low confidence (0); catalogued as rs982218682; called by muse, varscan2
- ASIC1 | c.1439C>T p.A480V | Missense Mutation (SNP) | VAF 54/387 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as rs750518534; called by muse, mutect2, varscan2
- DSCAML1 | c.1594G>A p.V532I (on ENST00000321322; = p.V472I on NM_020693.4) | Missense Mutation (SNP) | VAF 75/431 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.03); catalogued as rs748297167, COSV58383859; called by muse, mutect2, varscan2
- GPR62 | c.121C>T p.R41C | Missense Mutation (SNP) | VAF 86/542 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV59055832; called by muse, mutect2, varscan2
- PHACTR3 | c.1186C>T p.R396W | Missense Mutation (SNP) | VAF 34/189 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs763187430, COSV63030491; called by muse, mutect2, varscan2
- SNRNP25 | c.55G>A p.D19N (on ENST00000383018; = p.D10N on NM_024571.4) | Missense Mutation (SNP) | VAF 169/879 reads (19%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.643); catalogued as rs774466429; called by muse, mutect2, varscan2
- ZNFX1 | c.5335_5337del p.K1779del | In Frame Del (DEL) | VAF 30/200 reads (15%) | catalogued as rs746462561; called by pindel, varscan2
- ABCC6 | c.4285A>G p.T1429A | Missense Mutation (SNP) | VAF 21/414 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2
- ACSS2 | c.2044A>G p.T682A | Missense Mutation (SNP) | VAF 67/414 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- DGCR2 | c.489del p.F163Lfs*132 | Frame Shift Del (DEL) | VAF 75/642 reads (12%) | called by mutect2, pindel, varscan2
- FAM160B1 | c.263T>A p.L88* | Nonsense Mutation (SNP) | VAF 45/236 reads (19%) | called by muse, varscan2
- GALR2 | c.640C>T p.L214F | Missense Mutation (SNP) | VAF 46/193 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- INPPL1 | c.3691A>C p.I1231L | Missense Mutation (SNP) | VAF 32/226 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- INPPL1 | c.3692T>A p.I1231N | Missense Mutation (SNP) | VAF 32/221 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- ITPR3 | c.3196G>T p.D1066Y | Missense Mutation (SNP) | VAF 81/530 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); called by muse, mutect2, varscan2
- LRRK2 | c.2103A>T p.K701N | Missense Mutation (SNP) | VAF 10/218 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.511); called by muse, mutect2
- RNF128 | c.64A>C p.I22L | Missense Mutation (SNP) | VAF 33/64 reads (52%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- TRIP12 | c.391del p.S131Afs*27 | Frame Shift Del (DEL) | VAF 46/232 reads (20%) | called by mutect2, pindel, varscan2
- CLMN | c.2392C>T p.L798= | Silent (SNP) | VAF 14/142 reads (10%) | catalogued as rs1027075170; called by muse, mutect2
- HEPACAM2 | c.960C>T p.N320= (on ENST00000394468 / NM_001039372.4; = p.N308= on NM_198151.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 25/134 reads (19%) | called by muse, mutect2, varscan2
- MMRN1 | c.585T>C p.T195= | Silent (SNP) | VAF 48/248 reads (19%) | called by mutect2, varscan2
- NSD1 | c.7332G>A p.Q2444= | Silent (SNP) | VAF 163/1287 reads (13%) | catalogued as COSV100728611; called by muse, mutect2, varscan2
- SLC9A2 | c.1332G>A p.A444= | Silent (SNP) | VAF 42/565 reads (7%) | catalogued as rs539921286; called by muse, mutect2
- SPIDR | c.961T>C p.L321= | Silent (SNP) | VAF 127/598 reads (21%) | catalogued as rs371683101; called by muse, mutect2, varscan2
- AGPAT4 | c.348+5015C>A | Intron (SNP) | VAF 40/362 reads (11%) | called by muse, mutect2, varscan2
- FLI1 | c.231-3466C>T | Intron (SNP) | VAF 125/859 reads (15%) | catalogued as rs749536637; called by muse, mutect2, varscan2
- GPD1 | c.360+168G>C | Intron (SNP) | VAF 51/410 reads (12%) | called by muse, mutect2, varscan2
- KCNJ2 | c.*34C>T | 3'UTR (SNP) | VAF 32/298 reads (11%) | called by muse, mutect2, varscan2
